Surgical pathology report (de-identified scan), TCGA case TCGA-06-0151, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0151-01A (Primary Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology

Sex: Female Room/Bed:

Patient Name: _____ MRN: _____

PATIENT NAME:
HOSP. NO.:
ORDERING PHYSICIAN:

AGE/SEX:

F

ACC. NO.

NAME

PHYSICIAN:

PATH. NO.:

MED. REC. NO.:

SURGERY DATE:
RECEIVE DATE:

PATHOLOGICAL DIAGNOSIS:

BRAIN, RIGHT TEMPORAL LOBE, EXCISION: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: Brain, right temporal lobe.

Clinical History and Pre-Op Dx: Patient with minimal neurological symptoms who has a well demarcated, necrotizing lesion in the right temporal lobe.

INTRAOPERATIVE CONSULTATION: Glioma, high grade

GROSS PATHOLOGY: Specimen received in two separate containers, each labelled with the patient's name and MRN. They consist of multiple fragments of semi-firm tissue showing areas of necrosis and/or hemorrhage. The multiple fragments received measure in the aggregate approximately 5.0 gm and they are submitted in cassettes labelled 1-3, those received in the first container. The second container, which includes specimen of a similar feature, measuring about 2.5 cm in length, are entirely submitted in cassette labelled 4.

MICROSCOPIC: All fragments show the same appearance. The neoplasm has completely effaced the structure of the brain and there are multiple enlarged areas of coagulation necrosis. The tumor is very well vascularized and in many places the vessels are surrounded by abundant lymphocytes. Neoplastic cells are highly pleomorphic, small, and many show atypical mitosis. Most cells are highly undifferentiated, but a significant number have nuclear features and cytoplasm similar to those of a gemistocyte. Numerous vessels appear thrombosed and many of the neoplastic cells show abundant lipid droplets in the cytoplasm.

The neoplasm is highly anaplastic but most features are compatible with those of a glial derivation. Additional sections will be reacted with antisera against GFAP, S-100 protein, and MIB. When these are available, an addendum will be issued.

TISSUE COMMITTEE CODE:
BILLING CODES

ADDENDUM REPORT

[page 2 of 2]
Patient Name:

MRN:

Immunohistochemical stains for GFAP and MIB-1 were performed on blocks 1 and 3.

The GFAP brings up the prominent gliofibrillary nature of the neoplasm. With the MIB-1, a 10-11% labeling index is determined.

COMMENT: The diagnosis of "Glioblastoma multiforme" rendered on remains unchanged. The MIB-1 index is 10-11%.

Source: NCI Genomic Data Commons file 0d0e6940-22da-4492-bc10-06c2e858c29b (TCGA-06-0151.1F3FA2E7-E496-439C-8396-B6CEB738E6B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).